Somatic mutation profile of tumor specimen TCGA-2Z-A9J2-01A (aliquot TCGA-2Z-A9J2-01A-11D-A382-10) from TCGA case TCGA-2Z-A9J2, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 71.6 years (26,134 days).
Specimen TCGA-2Z-A9J2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64eafeda-eb3b-4bfb-9982-ab9b8b12c3f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9J2-10A (Blood Derived Normal), aliquot TCGA-2Z-A9J2-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7a547f3-12e1-407d-b405-a906810b9cc6

The open-access MAF lists 87 somatic variants for this specimen: 67 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Frame Shift Del 5, Frame Shift Ins 4, Nonsense Mutation 4, Intron 2, In Frame Del 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABR | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV100214802; called by muse, mutect2, varscan2
- ADGRV1 | c.9306C>A p.Y3102* | Nonsense Mutation (SNP) | VAF 15/131 reads (11%) | catalogued as COSV101315519; called by muse, mutect2, varscan2
- AGRN | c.4249G>T p.G1417C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101038591; called by muse, mutect2, varscan2
- AL645922.1 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.399); catalogued as COSV100190664; called by muse, mutect2, varscan2
- ANKRD52 | c.1264del p.G423Afs*21 | Frame Shift Del (DEL) | VAF 17/77 reads (22%) | catalogued as COSV99921556; called by mutect2, pindel, varscan2
- AZGP1 | c.569T>A p.L190Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99447681; called by mutect2, varscan2
- BAP1 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56234115, COSV56235544, COSV56236745, COSV56241651; called by muse, mutect2, varscan2
- BCL6 | c.1410G>T p.M470I | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51654991, COSV99215390; called by muse, mutect2, varscan2
- BCR | c.918G>T p.E306D | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV100005989; called by muse, mutect2, varscan2
- C9orf72 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.641); catalogued as COSV101186485; called by muse, mutect2, varscan2
- CCSAP | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.362); catalogued as COSV99497263; called by muse, mutect2, varscan2
- CD5 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100759754; called by muse, mutect2, varscan2
- CEMIP2 | c.1846A>G p.T616A | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV100987235; called by muse, mutect2, varscan2
- CNOT1 | c.3407T>A p.M1136K | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV99799294; called by muse, mutect2, varscan2
- CNOT1 | c.1183A>G p.I395V | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1034072027, COSV100408536; called by muse, mutect2, varscan2
- CNTNAP5 | c.1898A>T p.Q633L | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV101443073; called by muse, mutect2
- CYP4B1 | c.788A>G p.E263G | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV99596816; called by muse, mutect2, varscan2
- DLEC1 | c.4216T>C p.S1406P | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100341505; called by muse, mutect2, varscan2
- DMXL2 | c.2764+1G>A p.X922_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99195976; called by muse, mutect2, varscan2
- DNAH2 | c.6329C>G p.P2110R | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV101209021; called by muse, mutect2, varscan2
- GJA4 | c.896G>C p.R299T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100654629; called by muse, mutect2, varscan2
- GPR37 | c.1055T>C p.L352S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100390548; called by muse, mutect2
- HLA-A | c.133C>G p.R45G | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as COSV100954295, COSV65143413; called by muse, mutect2, varscan2
- ITIH1 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99834946; called by muse, mutect2, varscan2
- KAT6A | c.191C>A p.S64* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as COSV99704419, COSV99705273; called by muse, mutect2, varscan2
- KCNA5 | c.1471G>T p.V491F | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV99363638; called by muse, mutect2, varscan2
- KIAA1614 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100851268; called by muse, mutect2, varscan2
- LCLAT1 | c.1195T>A p.Y399N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV100473515; called by muse, mutect2, varscan2
- MAP3K19 | c.3527A>G p.Y1176C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59637674; called by muse, mutect2, varscan2
- MCC | c.837G>T p.E279D | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs560764461, COSV100202064; called by muse, mutect2, varscan2
- MED17 | c.1406A>G p.D469G | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV99315733; called by muse, mutect2
- NCOR1 | c.6046C>T p.H2016Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as COSV99247539; called by muse, mutect2, varscan2
- NLRP10 | c.781A>C p.K261Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV100149481; called by muse, mutect2, varscan2
- OTOL1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100019756; called by muse, mutect2, varscan2
- PANX2 | c.1783C>A p.P595T | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99348004; called by muse, mutect2, varscan2
- PDIA4 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV99618291; called by muse, mutect2, varscan2
- PEX14 | c.86T>G p.I29S | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs748027790, COSV100749986; called by muse, mutect2, varscan2
- POTEE | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.385); catalogued as rs530416641, COSV100387015; called by muse, mutect2, varscan2
- PPHLN1 | c.1305T>G p.N435K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as rs964112926, COSV99871498; called by muse, mutect2
- PREP | c.691G>C p.G231R (on ENST00000369110; = p.G297R on NM_002726.5) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100963724; called by muse, mutect2, varscan2
- RIMS2 | c.4127A>T p.E1376V (on ENST00000666250 / NM_001348490.2; = p.E947V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99161147; called by muse, mutect2
- SASS6 | c.989A>T p.E330V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99790603; called by muse, mutect2, varscan2
- SH3TC2 | c.3634G>C p.V1212L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV100101222; called by muse, mutect2, varscan2
- SIRPA | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV100605033; called by muse, mutect2
- SLC9C2 | c.1909G>A p.V637I | Missense Mutation (SNP) | VAF 212/445 reads (48%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.588); catalogued as rs1450191848, COSV62948682; called by muse, mutect2, varscan2
- SLFNL1 | c.266C>A p.P89Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV100262797; called by muse, mutect2, varscan2
- SOX5 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1427905071, COSV58630336; called by muse, mutect2
- SZT2 | c.4757G>C p.S1586T (on ENST00000634258 / NM_001365999.1; = p.S1529T on NM_015284.4) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV100986888; called by muse, mutect2, varscan2
- TMEM139 | c.173T>C p.F58S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV100130854; called by muse, mutect2, varscan2
- TMEM17 | c.251T>C p.I84T | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV100107660; called by muse, mutect2
- TMEM176A | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV99133543; called by muse, mutect2, varscan2
- TTN | c.99452T>G p.F33151C (on ENST00000591111; = p.F25727C on NM_003319.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | PolyPhen benign (0.009); catalogued as COSV100595036; called by muse, mutect2, varscan2
- TUT4 | c.2222T>G p.M741R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV99931844; called by muse, mutect2, varscan2
- UPB1 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100387070; called by muse, mutect2, varscan2
- WASHC4 | c.2234T>C p.L745P | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100162136; called by muse, mutect2, varscan2
- XRCC5 | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV101079310; called by muse, mutect2, varscan2
- ZFHX4 | c.10132A>T p.K3378* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99256564; called by muse, mutect2, varscan2
- ARID1A | c.5624dup p.P1876Tfs*25 | Frame Shift Ins (INS) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- ARID4B | c.327dup p.G110Rfs*7 | Frame Shift Ins (INS) | VAF 46/181 reads (25%) | called by mutect2, pindel, varscan2
- FOXM1 | c.2284_2289del p.L762_Q763del | In Frame Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, pindel, varscan2
- HACD1 | c.32_38dup p.S14Qfs*98 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- HELZ | c.2606dup p.H869Qfs*2 | Frame Shift Ins (INS) | VAF 53/136 reads (39%) | called by mutect2, pindel, varscan2
- MTA1 | c.877del p.A293Pfs*28 | Frame Shift Del (DEL) | VAF 34/102 reads (33%) | called by mutect2, pindel, varscan2
- NUP54 | c.828del p.Q276Hfs*4 | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- PTPN13 | c.6565_6591del p.S2189_L2197del (on ENST00000411767 / NM_080683.3; = p.S2170_L2178del on NM_006264.3) | In Frame Del (DEL) | VAF 12/68 reads (18%) | called by pindel, varscan2
- WDR27 | c.1824_1831delinsG p.L609Cfs*30 | Frame Shift Del (DEL) | VAF 42/122 reads (34%) | called by pindel, varscan2*
- ZSCAN5B | c.1329del p.C444Afs*11 | Frame Shift Del (DEL) | VAF 40/133 reads (30%) | called by mutect2, pindel, varscan2
- ARHGAP29 | c.2076C>A p.A692= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV99557645; called by muse, mutect2, varscan2
- CFAP44 | c.918C>T p.T306= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as rs543988684, COSV99868930, COSV99869126; called by muse, mutect2, varscan2
- CUBN | c.2887T>C p.L963= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV100912075; called by muse, mutect2, varscan2
- FAAH2 | c.1389C>G p.V463= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as COSV100887153; called by muse, mutect2, varscan2
- KDM3A | c.33A>G p.V11= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs745968685, COSV100460020; called by muse, mutect2, varscan2
- KIF13B | c.1095C>A p.A365= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV101580533, COSV73054421; called by muse, mutect2, varscan2
- KIF1B | c.2952G>A p.L984= (on ENST00000377086 / NM_001365952.1; = p.L938= on NM_015074.3) | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs956831359, COSV99822506; called by muse, mutect2, varscan2
- MIDN | c.1047T>C p.T349= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV99960119; called by muse, mutect2, varscan2
- OR4C11 | c.192G>A p.L64= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as rs775489583, COSV100155208; called by muse, mutect2, varscan2
- OR51Q1 | c.189G>T p.L63= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV100332814; called by muse, mutect2
- PCDHGB7 | c.162A>C p.L54= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV99531107; called by muse, mutect2, varscan2
- PHF2 | c.1266C>T p.L422= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs758033401, COSV100823029; called by muse, mutect2, varscan2
- PRAMEF17 | c.567A>T p.S189= | Silent (SNP) | VAF 17/254 reads (7%) | catalogued as COSV101068669; called by muse, mutect2
- PRRC1 | c.513T>A p.I171= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV99687618; called by muse, mutect2
- RBM12 | c.2736T>C p.A912= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100467009; called by muse, mutect2, varscan2
- RRP7A | c.243C>T p.T81= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV100543724; called by muse, mutect2
- SH3BP4 | c.1203A>T p.I401= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100749003; called by muse, mutect2, varscan2
- ITGB2 | c.148-978G>T | Intron (SNP) | VAF 70/233 reads (30%) | catalogued as COSV100185633; called by muse, mutect2, varscan2
- MIR181A1 | n.34G>A | RNA (SNP) | VAF 9/100 reads (9%) | catalogued as rs1406655910; called by muse, mutect2
- NFASC | c.2471-1334G>A | Intron (SNP) | VAF 14/102 reads (14%) | catalogued as COSV100362844; called by muse, mutect2, varscan2
